Somatic mutation profile of tumor specimen MMRF_2097_1_BM_CD138pos (aliquot MMRF_2097_1_BM_CD138pos_T1_KHS5U_L08720) from MMRF case MMRF_2097, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,484 days).
Specimen MMRF_2097_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 870f7ef8-cb6a-4990-a790-7656d35e3573.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2097_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2097_2_PB_Whole_C1_KHS5U_L08719; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbba89ff-8ff9-4f4d-93f5-9c7ca8eebbd5

The open-access MAF lists 125 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 26, Silent 19, Intron 13, RNA 6, 5'UTR 4, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 3, 3'Flank 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPA | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774323189, CM990198, COSV53980884; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 46/155 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.2094G>T p.M698I | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1330180462; called by muse, mutect2, varscan2
- BNC2 | c.1982A>G p.N661S | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1440026546; called by muse, mutect2, varscan2
- C4orf54 | c.2351C>T p.T784M | Missense Mutation (SNP) | VAF 153/300 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs753999716, COSV72767137; called by muse, mutect2, varscan2
- CCDC89 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1167881777; called by muse, mutect2
- COL6A5 | c.5627C>G p.T1876R (on ENST00000312481; = p.T1872R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1430453154; called by muse, mutect2
- GRM1 | c.2041C>G p.R681G | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51118886, COSV51149197; called by muse, mutect2
- IGKV1-8 | c.149G>C p.S50T | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs544696468; called by muse, mutect2, varscan2
- IGLV3-1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs186574328; called by muse, varscan2
- IGLV3-1 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs541687060; called by muse, mutect2, varscan2
- LPCAT1 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.018); catalogued as rs766530725, COSV99359139; called by muse, mutect2, varscan2
- LYRM1 | c.210G>T p.R70S | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54643533; called by muse, mutect2, varscan2
- MAX | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, varscan2
- NDST1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as rs865891168; called by muse, mutect2
- NLRC4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs763335197, COSV61591140; called by muse, mutect2
- RBBP5 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs866967824; called by muse, mutect2, varscan2
- SLC25A13 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs186863471; called by muse, mutect2, varscan2
- VSX2 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1352241492, COSV56217842; called by muse, mutect2, varscan2
- APOB | c.4976A>G p.N1659S | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CAMK1G | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDH3 | c.1759T>A p.S587T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- CLCN3 | c.2394dup p.D799Rfs*44 | Frame Shift Ins (INS) | VAF 60/528 reads (11%) | called by mutect2, varscan2
- CTSC | c.440A>C p.E147A | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2
- DCTN1 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EYS | c.6609A>T p.L2203F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- F8 | c.5237T>C p.V1746A | Missense Mutation (SNP) | VAF 70/70 reads (100%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO41 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- GFRA1 | c.771A>G p.R257= | Splice Region (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- GPR137B | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- IGKV1-8 | c.73A>C p.T25P | Missense Mutation (SNP) | VAF 132/252 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRF1 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2
- KCNA5 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KIAA1217 | c.4439T>C p.I1480T | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPAR3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAX | c.108G>C p.R36S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MTR | c.3175A>G p.I1059V | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKNOX2 | c.936+1G>A p.X312_splice | Splice Site (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- RPRD1B | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2
- RUSC2 | c.2021del p.G674Afs*168 | Frame Shift Del (DEL) | VAF 81/324 reads (25%) | called by mutect2, pindel, varscan2
- SLIT2 | c.1435T>C p.S479P | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SORBS3 | c.180T>A p.N60K | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SVEP1 | c.8150del p.C2717Lfs*33 | Frame Shift Del (DEL) | VAF 20/191 reads (10%) | called by mutect2, pindel, varscan2
- SYTL4 | c.218T>A p.L73* | Nonsense Mutation (SNP) | VAF 143/250 reads (57%) | called by muse, mutect2, varscan2
- TBC1D12 | c.969C>T p.T323= | Splice Region (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2
- TGDS | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 33/36 reads (92%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.1353del p.Y452Tfs*27 | Frame Shift Del (DEL) | VAF 44/190 reads (23%) | called by mutect2, pindel, varscan2
- TNNI3K | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 24/566 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TRAF3 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF3 | c.1644T>A p.Y548* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- TSC2 | c.1576A>C p.S526R | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- VWA3A | c.350+7C>G | Splice Region (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- ZNF18 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC3 | c.3052T>C p.L1018= | Silent (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2
- ANKRD55 | c.750G>C p.L250= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- CADPS | c.1317T>A p.S439= | Silent (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- CARS1 | c.981G>A p.K327= | Silent (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- CDH18 | c.498T>G p.V166= | Silent (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- EPHA3 | c.1803A>C p.T601= | Silent (SNP) | VAF 26/510 reads (5%) | called by muse, mutect2
- FBXL13 | c.1743C>T p.I581= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- GPR50 | c.486C>T p.P162= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs375321133; called by muse, mutect2, varscan2
- IGHV2-70D | c.84T>C p.P28= | Silent (SNP) | VAF 56/59 reads (95%) | catalogued as rs1170739947; called by muse, varscan2
- IGLL5 | c.46C>T p.L16= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs564743210, COSV73249743, COSV73250317, COSV73251309; called by muse, mutect2, varscan2
- KCNH8 | c.3058T>C p.L1020= | Silent (SNP) | VAF 198/469 reads (42%) | catalogued as rs764185238; called by muse, mutect2, varscan2
- MAGED1 | c.702G>A p.Q234= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- NEBL | c.2883C>T p.A961= | Silent (SNP) | VAF 94/175 reads (54%) | called by muse, mutect2, varscan2
- NXPH2 | c.87G>A p.T29= | Silent (SNP) | VAF 112/225 reads (50%) | called by muse, mutect2, varscan2
- PTPRE | c.54G>A p.R18= | Silent (SNP) | VAF 32/377 reads (8%) | called by muse, mutect2
- RECQL | c.189T>C p.S63= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as rs967619221; called by muse, mutect2
- RNF166 | c.591C>T p.S197= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs377654103; called by muse, mutect2, varscan2
- SNAPC2 | c.606T>C p.F202= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs1568289442; called by muse, mutect2
- TTC6 | c.223A>C p.R75= | Silent (SNP) | VAF 139/143 reads (97%) | called by muse, mutect2, varscan2
- AC012236.1 | n.35A>G | RNA (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- AC092691.1 | n.273G>A | RNA (SNP) | VAF 20/37 reads (54%) | catalogued as rs951430230; called by muse, mutect2
- AC109583.1 | c.-1319+876G>A | Intron (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- AL591135.1 | n.4787C>T | RNA (SNP) | VAF 142/298 reads (48%) | called by muse, mutect2, varscan2
- BICD2 | c.2470-524T>G | Intron (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- BMP6 | c.*1135_*1182del | 3'UTR (DEL) | VAF 57/140 reads (41%) | called by mutect2, pindel
- C11orf96 | chr11:43943321 G>A | 3'Flank (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- CC2D2B | chr10:96032792 C>G | 3'Flank (SNP) | VAF 85/189 reads (45%) | called by muse, mutect2, varscan2
- DPP6 | c.2451+69G>A | Intron (SNP) | VAF 31/99 reads (31%) | catalogued as rs562327323; called by muse, mutect2, varscan2
- DRC3 | c.1203+13G>A | Intron (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- ESRRG | c.*173A>G | 3'UTR (SNP) | VAF 220/402 reads (55%) | called by muse, mutect2, varscan2
- FAIM2 | c.*946C>T | 3'UTR (SNP) | VAF 88/182 reads (48%) | called by muse, mutect2, varscan2
- FAM166C | c.462-276G>A | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as COSV56600456; called by muse, mutect2, varscan2
- GALNT10 | c.*3625C>A | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- GATA6 | c.*4C>T | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- HOXD1 | c.*497A>G | 3'UTR (SNP) | VAF 43/87 reads (49%) | catalogued as rs1298795476; called by mutect2, varscan2
- HTR5A | chr7:155067139 C>T | 5'Flank (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- IGLL5 | c.-87C>T | 5'UTR (SNP) | VAF 48/101 reads (48%) | catalogued as rs140924009; called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1438C>T | Intron (SNP) | VAF 54/94 reads (57%) | catalogued as rs1559594166; called by muse, mutect2
- JRK | c.*5496A>G | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- KNSTRN | c.*198A>T | 3'UTR (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- LETMD1 | c.274+23A>T | Intron (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- LNPK | c.-111A>C | 5'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- LRRC28 | c.*4050G>A | 3'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- LTO1 | c.227+125G>T | Intron (SNP) | VAF 92/187 reads (49%) | called by muse, mutect2, varscan2
- MARK2 | c.-572G>A | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- MST1L | n.3748A>G | RNA (SNP) | VAF 141/571 reads (25%) | catalogued as rs1202131047; called by muse, mutect2, varscan2
- NAALADL2 | c.*658C>A | 3'UTR (SNP) | VAF 72/127 reads (57%) | catalogued as COSV71987060; called by muse, mutect2, varscan2
- NACC2 | c.*1206G>C | 3'UTR (SNP) | VAF 63/456 reads (14%) | called by muse, mutect2, varscan2
- NAPSB | n.909A>G | RNA (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- NIPA1 | c.*4670G>C | 3'UTR (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5440G>T | Intron (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1929G>A | 3'UTR (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*1371A>G | 3'UTR (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- PSEN1 | c.*4041G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- RAB11FIP2 | c.*1874T>A | 3'UTR (SNP) | VAF 14/145 reads (10%) | catalogued as COSV62925418; called by muse, mutect2, varscan2
- RGS18 | c.*246A>C | 3'UTR (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- RIN2 | c.*1141del | 3'UTR (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- RPS6KB2 | c.78+100C>T | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- SLC36A3 | c.-107A>G | 5'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- SLC66A2 | c.*615G>T | 3'UTR (SNP) | VAF 54/477 reads (11%) | called by muse, mutect2, varscan2
- SLF2 | c.2042+140T>A | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- SQSTM1 | c.*573C>G | 3'UTR (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- SSPOP | n.11889C>A | RNA (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- THSD4 | c.*3963G>A | 3'UTR (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- TNRC6B | c.*8431A>C | 3'UTR (SNP) | VAF 20/48 reads (42%) | catalogued as rs1314555771, COSV100109203; called by mutect2, varscan2
- TSHZ3 | c.*659T>G | 3'UTR (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- UNC5C | c.*3998G>A | 3'UTR (SNP) | VAF 31/56 reads (55%) | catalogued as rs888873092; called by muse, mutect2
- USP26 | c.*150C>T | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- ZFAND6 | c.-181+13468T>A | Intron (SNP) | VAF 130/477 reads (27%) | called by muse, mutect2, varscan2
- ZNF606 | c.*754A>T | 3'UTR (SNP) | VAF 68/147 reads (46%) | called by muse, mutect2, varscan2
- ZNF707 | c.256+49C>A | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
